Gene-level copy-number profile of tumor specimen TCGA-CD-5798-01A from TCGA case TCGA-CD-5798, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 83.0 years (30,310 days).
Specimen TCGA-CD-5798-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a1a99b6a-079e-461e-993d-772975b89275.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5798-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1af33e73-de1b-4131-9b42-26f75cbca6fc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 4,521; copy number 2: 52,727; copy number 3: 2,483; copy number 4: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-5798-01A-11D-1599-01): tumor purity 0.19, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:2,921,496–3,601,403, 7 genes (within-gene range 0–1): AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1.
- chr12:51,281,038–52,015,889, 19 genes: BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
